Somatic mutation profile of tumor specimen ALCH-AF3G-TTP1-A (aliquot ALCH-AF3G-TTP1-A-1-0-D-A627-36) from ALCHEMIST case ALCH-AF3G, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Pleomorphic carcinoma; Age at diagnosis: 41.0 years (14,968 days).
Specimen ALCH-AF3G-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 046675db-1d91-40d7-8ced-b3e9cdd7b3c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AF3G-NB1-A (Blood Derived Normal), aliquot ALCH-AF3G-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eea05d54-00a9-40a9-855f-06e90008bddd

The open-access MAF lists 42 somatic variants for this specimen: 31 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 7, Splice Site 3, Intron 2, RNA 1, Frame Shift Ins 1, 3'UTR 1, Splice Region 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 102/309 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.856_861del p.E286_E287del | In Frame Del (DEL) | VAF 152/537 reads (28%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- FAM184A | c.1673T>C p.M558T | Missense Mutation (SNP) | VAF 73/261 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs534170426; called by muse, mutect2, varscan2
- IGSF10 | c.2200C>A p.H734N | Missense Mutation (SNP) | VAF 20/400 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1235555342; called by muse, mutect2
- MYH6 | c.5368C>A p.Q1790K | Missense Mutation (SNP) | VAF 137/382 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs777333999; called by muse, mutect2, varscan2
- NLRP4 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 103/287 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.153); catalogued as rs746135586, COSV56707809; called by muse, mutect2, varscan2
- OR10AG1 | c.359C>A p.P120H | Missense Mutation (SNP) | VAF 72/245 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV56634735; called by muse, mutect2, varscan2
- PLEKHA4 | c.366+1G>A p.X122_splice | Splice Site (SNP) | VAF 89/465 reads (19%) | catalogued as rs756926315; called by muse, mutect2, varscan2
- SATB2 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 212/900 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV53489382; called by muse, mutect2, varscan2
- SERPINA12 | c.1094C>T p.T365M | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.797); catalogued as rs772567326, COSV57942916; called by muse, mutect2, varscan2
- STOX1 | c.2558G>A p.R853K | Missense Mutation (SNP) | VAF 120/419 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV100057471; called by muse, mutect2, varscan2
- SUZ12 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 70/240 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.127); catalogued as rs1159062569; called by muse, varscan2
- ARHGAP28 | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 189/805 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, varscan2
- CCN2 | c.907G>A p.V303M | Missense Mutation (SNP) | VAF 299/1064 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- COPZ1 | c.169+5del | Splice Region (DEL) | VAF 98/368 reads (27%) | called by mutect2, pindel, varscan2
- DDX43 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 56/553 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.231); called by muse, mutect2
- DOP1B | c.4998+2_4998+5del p.X1666_splice | Splice Site (DEL) | VAF 34/124 reads (27%) | called by mutect2, pindel
- FSD2 | c.1270T>C p.F424L | Missense Mutation (SNP) | VAF 66/179 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.117); called by muse, varscan2
- KAT7 | c.16-1G>A p.X6_splice | Splice Site (SNP) | VAF 85/300 reads (28%) | called by muse, mutect2, varscan2
- KNDC1 | c.4452T>A p.F1484L | Missense Mutation (SNP) | VAF 56/229 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- MIER3 | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 80/448 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- MUC16 | c.2585G>A p.S862N | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MUC19 | c.696C>A p.S232R | Missense Mutation (SNP) | VAF 110/480 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- RPA3 | c.118dup p.M40Nfs*21 | Frame Shift Ins (INS) | VAF 85/416 reads (20%) | called by mutect2, pindel, varscan2
- STEAP2 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 65/278 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- TLE2 | c.508G>T p.V170F | Missense Mutation (SNP) | VAF 56/159 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TRIM17 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 40/218 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- USP28 | c.1735C>T p.L579F | Missense Mutation (SNP) | VAF 358/1043 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- WIF1 | c.657G>C p.M219I | Missense Mutation (SNP) | VAF 122/646 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.028); called by muse, varscan2
- ZMYM2 | c.3605G>T p.W1202L | Missense Mutation (SNP) | VAF 139/550 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ZNF568 | c.435C>G p.Y145* | Nonsense Mutation (SNP) | VAF 70/288 reads (24%) | called by muse, mutect2
- BRDT | c.705C>T p.F235= | Silent (SNP) | VAF 94/376 reads (25%) | called by muse, mutect2, varscan2
- BSN | c.6957C>T p.I2319= | Silent (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- GSTO1 | c.223C>T p.L75= | Silent (SNP) | VAF 226/1007 reads (22%) | catalogued as COSV63846690; called by muse, mutect2, varscan2
- LMTK2 | c.3864C>T p.D1288= | Silent (SNP) | VAF 73/269 reads (27%) | catalogued as rs551486715, COSV52003176; called by muse, mutect2, varscan2
- LZTR1 | c.1494C>T p.G498= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs772242645; called by muse, mutect2, varscan2
- TANGO6 | c.2208C>T p.V736= | Silent (SNP) | VAF 136/537 reads (25%) | catalogued as rs993901368; called by muse, mutect2, varscan2
- TLL2 | c.2217C>T p.D739= | Silent (SNP) | VAF 51/187 reads (27%) | called by muse, mutect2, varscan2
- ACRBP | c.*1G>A | 3'UTR (SNP) | VAF 30/136 reads (22%) | catalogued as rs1381944000; called by muse, varscan2
- CTHRC1 | c.150+779C>A | Intron (SNP) | VAF 72/357 reads (20%) | called by muse, mutect2, varscan2
- MIR216A | n.43T>A | RNA (SNP) | VAF 61/247 reads (25%) | catalogued as rs757996659; called by muse, mutect2, varscan2
- SMARCD3 | c.1037+38G>T | Intron (SNP) | VAF 142/564 reads (25%) | called by muse, mutect2, varscan2
